Gene-level copy-number profile of tumor specimen TCGA-13-A5FT-01A from TCGA case TCGA-13-A5FT, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.7 years (24,743 days).
Specimen TCGA-13-A5FT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.948a6d77-e8ca-4114-add3-77e7db75b3b3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-A5FT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 835 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c45bf2cd-4750-4fce-9617-07a2baef8c7c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 15,484; copy number 2: 34,683; copy number 3: 8,427; copy number 4: 785; copy number 5: 355; copy number 6: 16; copy number 7: 8; copy number 8: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-A5FT-01A-11D-A402-01): tumor purity 0.85, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:69,762,328–69,941,741, 3 genes (within-gene range 0–1): WWP2, SNORA62, MIR140.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 405 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:5,862,811–6,784,843, 31 genes, copy number 5: NPHP4, KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, AL591163.1, CAMTA1-DT.
- chr1:6,834,333–6,834,618, 1 gene, copy number 5: AL590128.1.
- chr1:75,127,830–75,611,116, 8 genes, copy number 5: AC099786.1, LHX8, AC099786.2, RNU6-622P, SLC44A5, AC093156.1, RNU6-503P, AL096829.1.
- chr2:41,819,747–42,332,548, 11 genes, copy number 5 (within-gene range 4–5): LDHAP3, RPS12P4, Y_RNA, LINC01913, RNU4-63P, LINC01914, C2orf91, AC013480.1, PKDCC, EML4-AS1, EML4.
- chr2:43,219,849–43,596,046, 6 genes, copy number 8 (within-gene range 4–8): AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P.
- chr2:81,967,079–82,538,711, 6 genes, copy number 5–8: RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1.
- chr2:111,898,607–112,029,561, 4 genes, copy number 5 (within-gene range 3–5): MERTK, RN7SL297P, RTRAFP1, SLC30A6P1.
- chr3:41,687,868–42,342,367, 15 genes, copy number 6: AC099537.1, RN7SKP58, ATP6V0E1P2, Y_RNA, U8, RPL36P20, GEMIN2P2, TRAK1, AC093414.1, TPMTP2, RNU4-78P, CCK, AC018358.1, SALL4P6, EIF4BP4.
- chr3:149,517,235–149,736,714, 1 gene, copy number 5 (within-gene range 4–5): WWTR1.
- chr3:149,648,997–150,050,788, 13 genes, copy number 5: WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24.
- chr3:150,050,729–150,080,117, 2 genes, copy number 5: AC022494.1, LINC01998.
- chr3:154,007,367–155,988,176, 38 genes, copy number 5: U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2, AC073359.1, MME, MME-AS1, LINC01487, STRIT1, AC104831.1, PABPC1P10, PLCH1, AC108729.3, AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2, RPL6P7, AC104472.1, AC104472.2, C3orf33, AC104472.3, SLC33A1, AC104472.4, GMPS, AC104472.5, SETP14.
- chr3:165,772,904–166,294,353, 7 genes, copy number 5–7: BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1.
- chr3:168,666,559–168,928,598, 5 genes, copy number 5: RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2.
- chr3:177,010,719–178,007,779, 18 genes, copy number 5: MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P.
- chr6:93,811,825–94,447,179, 8 genes, copy number 5: AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr11:65,170,154–65,797,219, 53 genes, copy number 5: SPDYC, PGAM1P8, AP003068.2, CAPN1, SLC22A20P, AP000944.6, POLA2, AP000944.5, AP000944.7, CDC42EP2, DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1, KCNK7, MAP3K11, PCNX3, MIR4690, SIPA1, MIR4489, RELA, RELA-DT, RN7SL309P, KAT5, RNASEH2C, KRT8P26, AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1.
- chr12:24,566,964–25,409,445, 23 genes, copy number 5: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1.
- chr12:25,423,600–25,424,942, 1 gene, copy number 5: AC092451.2.
- chr12:94,491,546–94,650,557, 8 genes, copy number 5–7: AC023161.1, RN7SL483P, NSA2P2, SUCLG2P2, MIR5700, TMCC3, MIR7844, LSM3P2.
- chr12:124,513,222–124,989,131, 18 genes, copy number 8: AC073592.1, AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6, AC073592.8, AC073592.2, AC073592.10, AC073592.4, AC073593.1, SCARB1, AC073593.2, RNU6-927P, UBC, MIR5188, RPL22P19, DHX37.
- chr14:22,197,446–22,482,959, 1 gene, copy number 5 (within-gene range 3–5): AC244502.1.
- chr14:22,265,749–22,479,582, 24 genes, copy number 5: TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56.
- chr14:102,545,254–103,562,831, 40 genes, copy number 5: LINC02323, RN7SL546P, RCOR1, RPL23AP11, Y_RNA, AL132801.1, TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1, RPL13P6, LBHD2, AL161669.1, EXOC3L4, AL161669.4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13, RAP2CP1, AL138976.1, AL138976.2, EIF5, SNORA28, HMGB3P26, RPSAP5, MARK3, RPL10AP1, CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5.
- chr14:103,567,405–103,567,545, 1 gene, copy number 5: RNU4-68P.
- chr14:104,293,678–105,065,445, 30 genes, copy number 5: AL512357.2, AL512357.1, RNU6-684P, CEND1P1, TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2, CLBA1, CDCA4, GPR132.
- chr15:89,471,398–90,082,207, 32 genes, copy number 5: RHCG, LINC00928, AC013391.3, AC013391.2, TICRR, AC013391.1, KIF7, PLIN1, PEX11A, RPL36AP43, WDR93, AC079075.1, RNU6-132P, MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7.

Autosomal genes at a single copy (total copy number 1): 14,986. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
